Somatic mutation profile of tumor specimen TCGA-BP-4161-01A (aliquot TCGA-BP-4161-01A-02D-1386-10) from TCGA case TCGA-BP-4161, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 74.2 years (27,119 days).
Specimen TCGA-BP-4161-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 382c8ae0-7480-4a7c-8378-d318adcf1cc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4161-11A (Solid Tissue Normal), aliquot TCGA-BP-4161-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da68a2d6-ec9d-4147-9eda-c0675a28cd3e

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD50 | c.137G>C p.S46T | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.007); catalogued as rs1013129111, COSV72385879; called by muse, mutect2, varscan2
- ATF4 | c.406dup p.Q136Pfs*44 | Frame Shift Ins (INS) | VAF 52/242 reads (21%) | catalogued as rs770192882; called by mutect2, varscan2
- ATRNL1 | c.359C>A p.T120N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61808622; called by muse, mutect2, varscan2
- BAZ2B | c.5488G>T p.E1830* | Nonsense Mutation (SNP) | VAF 22/149 reads (15%) | catalogued as COSV58604465; called by muse, mutect2, varscan2
- BIN2 | c.603-2A>T p.X201_splice | Splice Site (SNP) | VAF 116/303 reads (38%) | catalogued as COSV57206395; called by muse, mutect2, varscan2
- CFAP61 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs764337986, COSV55636211; called by muse, mutect2, varscan2
- COL2A1 | c.3819G>T p.E1273D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV61532026; called by muse, mutect2, varscan2
- ELF1 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV53500194; called by muse, mutect2, varscan2
- EPAS1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs769717276, COSV55387929; called by muse, mutect2, varscan2
- FBN3 | c.1246A>C p.T416P | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV54465084; called by muse, mutect2, varscan2
- FNBP1L | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774614978, COSV53091412; called by muse, mutect2, varscan2
- GPAT4 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 20/626 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67841248; called by muse, mutect2
- GPR179 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs746508651; called by muse, mutect2, varscan2
- GRK3 | c.1733G>T p.R578L | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV60797783, COSV60798709; called by muse, mutect2, varscan2
- KIF13A | c.3507G>A p.M1169I | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV52456674, COSV99433136; called by muse, mutect2, varscan2
- LRRCC1 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV64484131; called by muse, mutect2
- MED14 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 278/444 reads (63%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as COSV61355908, COSV61357535; called by muse, varscan2
- MUC7 | c.430A>T p.N144Y | Missense Mutation (SNP) | VAF 143/439 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV59219192; called by muse, mutect2, varscan2
- NUP153 | c.4034C>T p.S1345L | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs770689640, COSV50453466; called by muse, mutect2, varscan2
- OR2G2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60740372; called by muse, mutect2, varscan2
- PALLD | c.828G>C p.K276N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54985367; called by muse, mutect2
- PBRM1 | c.384G>A p.K128= | Splice Region (SNP) | VAF 64/239 reads (27%) | catalogued as COSV56285794; called by muse, mutect2, varscan2
- PCDH15 | c.4979C>T p.A1660V | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64707294, COSV64716235; called by muse, mutect2, varscan2
- PCDHGC5 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52757508; called by muse, mutect2, varscan2
- PCLO | c.8114T>C p.L2705P | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV61646470; called by muse, mutect2, varscan2
- PDGFRB | c.1769A>C p.D590A | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV55807103; called by muse, mutect2, varscan2
- PPP1R15A | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs1176927279, COSV52339537; called by muse, mutect2
- PRPH | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV57679028; called by muse, mutect2, varscan2
- RASAL3 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs890076731, COSV54604207; called by muse, mutect2, varscan2
- RIMS1 | c.3757C>G p.P1253A | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV53465857; called by muse, mutect2, varscan2
- SDAD1 | c.477+1G>A p.X159_splice | Splice Site (SNP) | VAF 53/175 reads (30%) | catalogued as COSV62403222; called by muse, mutect2, varscan2
- SELENON | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV62525254; called by muse, mutect2, varscan2
- SLAMF1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs757926113, COSV52499389, COSV52500217; called by muse, mutect2, varscan2
- SLC2A3 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV50004535; called by muse, mutect2, varscan2
- SMARCA2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61809448; called by muse, mutect2, varscan2
- TDRD1 | c.766A>T p.R256* | Nonsense Mutation (SNP) | VAF 41/165 reads (25%) | catalogued as COSV52592522; called by muse, mutect2, varscan2
- TTN | c.54158G>T p.C18053F (on ENST00000591111; = p.C10629F on NM_003319.4) | Missense Mutation (SNP) | VAF 30/167 reads (18%) | PolyPhen benign (0.136); catalogued as COSV60168084; called by muse, mutect2, varscan2
- UBR2 | c.3195G>T p.Q1065H | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV65750881; called by muse, mutect2, varscan2
- UNC13B | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 70/242 reads (29%) | catalogued as COSV65936082; called by muse, mutect2, varscan2
- USH2A | c.8410G>A p.G2804R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56393451; called by muse, mutect2, varscan2
- WIZ | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1223843250, COSV54609335; called by muse, mutect2
- ADORA2A | c.125del p.N42Tfs*75 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- ANK3 | c.8781del p.V2928Sfs*8 | Frame Shift Del (DEL) | VAF 59/247 reads (24%) | called by mutect2, pindel, varscan2
- CDK13 | c.4241del p.A1414Vfs*129 | Frame Shift Del (DEL) | VAF 54/200 reads (27%) | called by mutect2, pindel, varscan2
- ERICH5 | c.432del p.G145Efs*8 | Frame Shift Del (DEL) | VAF 37/117 reads (32%) | called by mutect2, pindel, varscan2
- PBRM1 | c.5068del p.*1690Nfs*? (on ENST00000296302 / NM_001366071.2; = p.*1583Nfs*64 on NM_018313.5) | Frame Shift Del (DEL) | VAF 77/295 reads (26%) | called by mutect2, pindel, varscan2
- PROSER3 | c.796_820del p.T266Pfs*39 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- SETD2 | c.7325dup p.T2443Nfs*3 | Frame Shift Ins (INS) | VAF 89/239 reads (37%) | called by mutect2, pindel, varscan2
- CEP97 | c.1296T>C p.D432= | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as COSV59125697; called by muse, mutect2, varscan2
- LRP2 | c.13488T>G p.P4496= | Silent (SNP) | VAF 50/207 reads (24%) | catalogued as COSV55560664; called by muse, mutect2, varscan2
- LYPD3 | c.75C>T p.R25= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs755532944, COSV54988338; called by muse, mutect2, varscan2
- MAD1L1 | c.873G>A p.G291= | Silent (SNP) | VAF 83/220 reads (38%) | catalogued as COSV56239164; called by muse, mutect2, varscan2
- MUC16 | c.40830C>A p.T13610= | Silent (SNP) | VAF 52/148 reads (35%) | catalogued as rs369873764, COSV66694188; called by muse, mutect2, varscan2
- MXRA5 | c.7608G>A p.L2536= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- MYBBP1A | c.3873A>T p.P1291= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV54599766; called by muse, mutect2, varscan2
- PDGFRB | c.1770C>T p.D590= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV55807088; called by muse, mutect2, varscan2
- PIK3C2G | c.4140G>A p.E1380= (on ENST00000676171; = p.E1339= on NM_004570.5) | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV56809721; called by muse, mutect2, varscan2
- POLR2A | c.4146G>T p.L1382= | Silent (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.1245G>T p.S415= | Silent (SNP) | VAF 108/346 reads (31%) | catalogued as rs577498680, COSV53939736, COSV53940841; called by muse, mutect2, varscan2
- TFR2 | c.213C>T p.L71= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV50516053; called by muse, mutect2, varscan2
- ZNF221 | c.243C>T p.F81= | Silent (SNP) | VAF 64/213 reads (30%) | catalogued as COSV52110078; called by muse, mutect2, varscan2
- PDE4DIP | c.637-7430C>T | Intron (SNP) | VAF 21/102 reads (21%) | catalogued as COSV57707079; called by muse, mutect2, varscan2
